Gene-level copy-number profile of tumor specimen MP2PRT-PARPYH-TMP1-A from MP2PRT case MP2PRT-PARPYH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Precursor cell lymphoblastic leukemia, not phenotyped; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,105 days).
Specimen MP2PRT-PARPYH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 396ec54e-648a-4461-bb95-40091f25746f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARPYH-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,741 have no estimate.
https://portal.gdc.cancer.gov/files/da876f7e-9206-4985-87d1-240871beb50d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 386; copy number 1: 4,173; copy number 2: 53,469; copy number 3: 854.

Homozygous deletions (total copy number 0; autosomes only): 383 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,525,805–27,530,561, 1 gene: BX293535.1.
- chr2:88,811,186–89,275,787, 43 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34.
- chr2:89,968,867–90,005,629, 4 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24.
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,273,587–38,330,935, 10 genes (within-gene range 0–1): TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr7:142,636,924–142,802,748, 29 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr9:36,833,269–37,120,446, 10 genes (within-gene range 0–2): PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2.
- chr9:37,160,137–37,160,237, 1 gene (within-gene range 0–2): Y_RNA.
- chr10:109,996,368–110,135,565, 1 gene (within-gene range 0–2): ADD3.
- chr12:13,000,451–13,142,521, 4 genes (within-gene range 0–2): AC023790.2, AC023790.1, FAM234B, GSG1.
- chr14:22,168,429–22,552,156, 84 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,771,020, 161 genes (within-gene range 0–2) (broad region; genes not listed).
- chr18:13,217,498–13,652,755, 15 genes (within-gene range 0–2): LDLRAD4, AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1.
- chr22:22,103,219–22,245,515, 17 genes: AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.
- chr22:22,893,692–22,895,834, 2 genes (within-gene range 0–1): IGLJ1, IGLC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,320. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
